Somatic mutation profile of tumor specimen TCGA-19-1385-01A (aliquot TCGA-19-1385-01A-02W-0643-08) from TCGA case TCGA-19-1385, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.7 years (25,459 days).
Specimen TCGA-19-1385-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1aedce8a-f0c9-4a67-beff-b29bad296eb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-1385-10C (Blood Derived Normal), aliquot TCGA-19-1385-10C-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97a040ad-48f0-4579-b812-47e08f0bfb5f

The open-access MAF lists 63 somatic variants for this specimen: 45 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 16, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 2, 5'UTR 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.6819+1G>A p.X2273_splice (on ENST00000358273 / NM_001042492.3; = p.X2252_splice on NM_000267.3) | Splice Site (SNP) | VAF 11/136 reads (8%) | catalogued as rs1555534964, CS000887, COSV62201315, COSV62218236; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA8 | c.1022G>A p.W341* | Nonsense Mutation (SNP) | VAF 12/237 reads (5%) | catalogued as rs916527040, COSV99287133; called by muse, mutect2
- AQP4 | c.102C>A p.F34L | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as COSV101270573; called by muse, mutect2
- ARHGAP21 | c.2653G>A p.G885S | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1490798271, COSV100256786; called by muse, mutect2, varscan2
- BRD2 | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 384/994 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV100875872; called by muse, mutect2, varscan2
- BRWD3 | c.623C>G p.A208G | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV100956636, COSV64748858; called by muse, mutect2
- C9orf64 | c.651G>C p.W217C | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100123679; called by muse, mutect2, varscan2
- CFAP58 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 77/104 reads (74%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100459153; called by muse, mutect2, varscan2
- CHD4 | c.1778C>A p.A593E (on ENST00000357008 / NM_001363606.2; = p.A606E on NM_001273.5) | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV100539449; called by muse, mutect2
- CLSPN | c.2688G>T p.L896F | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231696; called by muse, mutect2
- COL4A2 | c.2134G>T p.A712S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.138); catalogued as COSV100847519; called by muse, mutect2
- CRACDL | c.463T>A p.S155T | Missense Mutation (SNP) | VAF 578/680 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1324933327, COSV101194169; called by mutect2, varscan2
- ERBIN | c.4022G>C p.G1341A (on ENST00000284037 / NM_001253697.2; = p.G1300A on NM_018695.4) | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99398002; called by muse, mutect2, varscan2
- FLG | c.3850G>A p.E1284K | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs757534632, COSV100912370; called by muse, varscan2
- GFPT1 | c.883G>A p.E295K (on ENST00000357308 / NM_001244710.2; = p.E277K on NM_002056.4) | Missense Mutation (SNP) | VAF 236/648 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs764200601, COSV61948198; called by muse, mutect2, varscan2
- GLI3 | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101230130; called by muse, mutect2
- GPATCH8 | c.991G>T p.G331* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | catalogued as COSV100132920; called by muse, mutect2, varscan2
- GPNMB | c.1601A>C p.N534T (on ENST00000381990 / NM_001005340.2; = p.N522T on NM_002510.3) | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.052); catalogued as COSV99326902; called by muse, mutect2
- GRIN3A | c.2766G>T p.E922D | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100701921; called by muse, mutect2, varscan2
- HDC | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as rs749549807, COSV51078964; called by muse, mutect2
- HECW2 | c.3355C>T p.R1119* | Nonsense Mutation (SNP) | VAF 82/152 reads (54%) | catalogued as COSV53650839; called by muse, mutect2, varscan2
- KBTBD4 | c.1319C>A p.S440Y | Missense Mutation (SNP) | VAF 90/435 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100442982; called by muse, mutect2, varscan2
- KCNN3 | c.1178C>A p.S393Y | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55212412, COSV99679453; called by muse, mutect2
- KLHL38 | c.1579G>A p.G527S | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100384659; called by muse, mutect2, varscan2
- KLHL5 | c.2145dup p.Y716Vfs*2 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | catalogued as rs1213171273; called by pindel, varscan2
- NTAN1 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 40/612 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99817160; called by muse, mutect2
- POPDC3 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 107/166 reads (64%) | catalogued as COSV54645495, COSV99634096; called by muse, mutect2, varscan2
- ROS1 | c.2569C>A p.L857M | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752798332, COSV100877822; called by muse, mutect2, varscan2
- SLC30A2 | c.214C>A p.R72S | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV100958639, COSV65332725; called by muse, mutect2, varscan2
- SLC4A4 | c.782T>A p.I261N (on ENST00000264485 / NM_001098484.3; = p.I217N on NM_003759.4) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.392); catalogued as COSV99143225; called by muse, mutect2
- SPAG17 | c.650A>C p.D217A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100310906; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | PolyPhen probably damaging (1); catalogued as rs141702482; called by muse, mutect2, varscan2
- TCF23 | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV99940445; called by muse, mutect2
- TM9SF2 | c.347A>T p.K116M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV100899788; called by mutect2, varscan2
- TUT4 | c.1733C>A p.T578N | Missense Mutation (SNP) | VAF 19/391 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.072); catalogued as COSV99932937; called by muse, mutect2
- WDR36 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV101551031; called by muse, mutect2, varscan2
- ZNF662 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100066713; called by muse, mutect2, varscan2
- ZNF77 | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 234/750 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as COSV100094704; called by muse, mutect2, varscan2
- ADNP | c.2908T>A p.S970T | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); called by muse, mutect2
- ALDH1L1 | c.2189A>G p.E730G | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.203); called by mutect2, varscan2
- CEP192 | c.6740del p.G2247Efs*18 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- FLG2 | c.6106_6107dup p.S2036Rfs*367 | Frame Shift Ins (INS) | VAF 68/405 reads (17%) | called by pindel, varscan2
- NPAT | c.2186del p.S729* | Frame Shift Del (DEL) | VAF 108/210 reads (51%) | called by mutect2, pindel, varscan2
- PDZRN3 | c.2142G>T p.Q714H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- SEC23IP | c.2000del p.K667Rfs*17 | Frame Shift Del (DEL) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.1878T>C p.I626= | Silent (SNP) | VAF 11/164 reads (7%) | catalogued as COSV100711763; called by muse, mutect2
- ANKRD17 | c.5949A>T p.T1983= | Silent (SNP) | VAF 125/1337 reads (9%) | catalogued as COSV58219050; called by muse, mutect2
- APOA4 | c.1107C>A p.S369= | Silent (SNP) | VAF 68/80 reads (85%) | catalogued as COSV100759405, COSV63361209; called by muse, mutect2, varscan2
- ARL8A | c.201C>T p.I67= | Silent (SNP) | VAF 9/159 reads (6%) | catalogued as COSV55342924, COSV99693424; called by muse, mutect2
- ATR | c.1488C>T p.V496= | Silent (SNP) | VAF 16/234 reads (7%) | catalogued as rs774470632, COSV63386717; called by muse, mutect2
- CLPTM1L | c.357C>T p.H119= | Silent (SNP) | VAF 42/179 reads (23%) | catalogued as rs1386239024, COSV100307400; called by muse, mutect2, varscan2
- COL6A3 | c.9480G>A p.K3160= | Silent (SNP) | VAF 30/295 reads (10%) | catalogued as rs113992704, COSV55083836, COSV99802203; called by muse, mutect2, varscan2
- CUL7 | c.228C>T p.A76= | Silent (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- FAP | c.2088C>A p.L696= | Silent (SNP) | VAF 10/190 reads (5%) | catalogued as COSV51859505, COSV51861591; called by muse, mutect2
- HCN3 | c.301C>T p.L101= | Silent (SNP) | VAF 58/109 reads (53%) | catalogued as rs563256073, COSV100855880; called by muse, mutect2, varscan2
- HCN3 | c.519C>T p.F173= | Silent (SNP) | VAF 48/60 reads (80%) | catalogued as COSV100855881; called by muse, mutect2, varscan2
- JADE3 | c.1074C>T p.F358= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99510436; called by muse, mutect2, varscan2
- MYO1A | c.567G>T p.V189= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV100271328, COSV55655375; called by muse, mutect2, varscan2
- OTUD5 | c.1014G>A p.V338= | Silent (SNP) | VAF 14/512 reads (3%) | catalogued as COSV99332326; called by muse, mutect2
- TNN | c.2769C>T p.D923= | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as rs199534795; called by muse, mutect2
- ZNF414 | c.504G>T p.L168= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV55321089; called by muse, mutect2
- PNOC | c.-2C>A | 5'UTR (SNP) | VAF 16/353 reads (5%) | catalogued as COSV100108430; called by muse, mutect2
- TTC8 | c.115-5742G>A | Intron (SNP) | VAF 8/89 reads (9%) | catalogued as COSV100581730; called by muse, mutect2
